CCDI case PBBUKM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/44e0cd4f-41a2-4a0e-989c-3eb52cf17443

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 10.3 years (3,776 days).

Biospecimens (2 samples)
- Sample 0DHX1V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHX36: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
